Somatic mutation profile of tumor specimen HTMCP-03-06-02357-01A (aliquot HTMCP-03-06-02357-01A-01D-9392) from CGCI case HTMCP-03-06-02357, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 54.1 years (19,778 days).
Specimen HTMCP-03-06-02357-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 164aa4ab-88d8-4a13-92da-45c08e284070.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02357-10A (Blood Derived Normal), aliquot HTMCP-03-06-02357-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec83285f-1bae-4fea-b5c5-266645111869

The open-access MAF lists 129 somatic variants for this specimen: 90 protein-altering or splice-affecting, 25 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 25, Nonsense Mutation 8, Intron 8, RNA 3, 5'Flank 2, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/78 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 55/120 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3203G>A p.G1068E | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54448848; called by muse, mutect2
- AHNAK | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as COSV57222143; called by muse, mutect2, varscan2
- AL592490.1 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425764; called by muse, mutect2, varscan2
- ALPK2 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs377635611; called by muse, mutect2, varscan2
- ATP8A1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52543545; called by muse, mutect2, varscan2
- BRINP3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748757778, COSV66531106; called by muse, mutect2
- CAPN8 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs772900742; called by muse, mutect2, varscan2
- CDC42BPB | c.2842C>T p.Q948* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV63474147; called by muse, mutect2, varscan2
- CDH10 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs747981734, COSV100049800, COSV52569461; called by muse, mutect2
- CEP57 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV100334891; called by muse, mutect2, varscan2
- CFAP44 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99870075; called by muse, mutect2, varscan2
- CSMD3 | c.4687G>A p.E1563K (on ENST00000297405 / NM_001363185.1; = p.E1459K on NM_052900.3) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV52317655; called by muse, mutect2, varscan2
- CUBN | c.5992G>C p.D1998H | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as COSV100912361; called by muse, mutect2
- EIF2AK3 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100304213; called by muse, mutect2, varscan2
- EP300 | c.1747C>G p.L583V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1339748510, COSV99610400; called by muse, mutect2
- F8 | c.4039G>C p.E1347Q | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as CM103778; called by muse, mutect2, varscan2
- FCRL5 | c.2666C>T p.P889L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV62514100; called by muse, mutect2, varscan2
- IPO9 | c.2962G>C p.E988Q | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV64233483; called by muse, mutect2
- KIAA1210 | c.4734G>C p.W1578C | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101273963, COSV68180513; called by muse, mutect2
- LRP1B | c.2287C>G p.Q763E | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV101258670; called by muse, mutect2
- MEGF9 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64235154; called by muse, mutect2, varscan2
- MET | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200423161, COSV59257142; called by muse, mutect2
- MKI67 | c.8449G>A p.D2817N | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.219); catalogued as rs372524784; called by muse, mutect2, varscan2
- NSUN4 | c.613C>T p.L205F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs776648035; called by muse, mutect2, varscan2
- NT5C2 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58414749; called by muse, mutect2, varscan2
- NWD1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1158651452; called by muse, mutect2, varscan2
- PCDHB14 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV53391001; called by muse, mutect2, varscan2
- PCDHB3 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV50564423; called by muse, mutect2, varscan2
- PDE5A | c.1812G>C p.K604N | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV53347785, COSV99309381; called by muse, mutect2, varscan2
- PHKA1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.021); catalogued as rs377254543; called by muse, mutect2, varscan2
- PIK3R1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs747881833, COSV99141381; called by muse, mutect2, varscan2
- POLA1 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100985776; called by muse, mutect2
- PRG4 | c.3032C>G p.A1011G | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as COSV63355070; called by muse, mutect2, varscan2
- QSER1 | c.5075C>T p.S1692L (on ENST00000399302; = p.S1821L on NM_001076786.3) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs779728370; called by muse, mutect2, varscan2
- SH3D21 | c.683G>A p.R228Q (on ENST00000453908 / NM_001162530.2; = p.R117Q on NM_024676.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1208225193, COSV57177184; called by muse, mutect2, varscan2
- SI | c.2100C>G p.Y700* | Nonsense Mutation (SNP) | VAF 28/191 reads (15%) | catalogued as rs765725418; called by muse, mutect2, varscan2
- SMARCA2 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100570521, COSV61806637; called by muse, mutect2, varscan2
- TEKT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139532367; called by muse, mutect2, varscan2
- TTN | c.85783G>A p.E28595K (on ENST00000591111; = p.E21171K on NM_003319.4) | Missense Mutation (SNP) | VAF 39/262 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs974510652; called by muse, mutect2, varscan2
- ULK4 | c.2362C>A p.P788T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs147474793; called by muse, mutect2, varscan2
- UTP20 | c.129G>A p.E43= | Splice Region (SNP) | VAF 14/118 reads (12%) | catalogued as rs1275866065; called by muse, mutect2
- WWC2 | c.3454G>A p.D1152N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV99067832; called by muse, mutect2, varscan2
- YEATS2 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1459723544, COSV59367175; called by muse, mutect2
- ZNF560 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56867546; called by muse, mutect2, varscan2
- ZNF560 | c.776C>G p.S259C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV56866754; called by muse, mutect2, varscan2
- ACSL4 | c.616G>A p.E206K (on ENST00000340800 / NM_022977.2; = p.E165K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2
- AHNAK | c.3523G>C p.E1175Q | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- AHNAK | c.1950G>A p.M650I | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD36C | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- APBB1IP | c.1215A>T p.R405S | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- BCLAF3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 35/399 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- BRD8 | c.1891G>A p.E631K (on ENST00000254900 / NM_139199.2; = p.E704K on NM_006696.4) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CARMIL1 | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CHD1 | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
- CMYA5 | c.4088C>G p.S1363* | Nonsense Mutation (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- CPLANE1 | c.251C>G p.S84* (on ENST00000425232; = p.S156* on NM_023073.3) | Nonsense Mutation (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- DCAF1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- EP300 | c.1746T>A p.H582Q | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG | c.4288C>G p.Q1430E | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FLNA | c.5191G>A p.V1731M (on ENST00000369850 / NM_001110556.2; = p.V1723M on NM_001456.3) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- GABRQ | c.611-1G>A p.X204_splice | Splice Site (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IGF2BP1 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LMBR1L | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEC2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- MICAL3 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 35/230 reads (15%) | called by muse, mutect2, varscan2
- NHS | c.2909C>T p.S970L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRXN3 | c.2113G>A p.E705K (on ENST00000335750 / NM_001330195.2; = p.E332K on NM_004796.6) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSCN | c.14776G>A p.D4926N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PDE1C | c.357G>C p.R119S | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PHKA1 | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- RC3H2 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RGSL1 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RIMS1 | c.2406G>C p.K802N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF20 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RTTN | c.3718C>T p.Q1240* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- SACS | c.13396C>T p.H4466Y | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SI | c.4699G>T p.D1567Y | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC9C2 | c.1088C>G p.S363* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- STRBP | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TENM2 | c.292T>C p.S98P | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOPORS | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPR | c.3893G>A p.R1298K | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- USP9X | c.7520C>T p.P2507L | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ZNF185 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ZNF521 | c.3152C>A p.A1051E | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2
- ZSWIM2 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADCY8 | c.345C>T p.S115= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs972171053, COSV53922804; called by muse, mutect2, varscan2
- BRD8 | c.3201C>T p.G1067= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV54725792; called by muse, mutect2, varscan2
- CACNA1C | c.5109C>T p.F1703= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs767569416; ClinVar: likely benign; called by muse, mutect2, varscan2
- CANT1 | c.927G>A p.E309= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- DNAH17 | c.9261C>T p.V3087= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs142391979; called by muse, mutect2, varscan2
- GPR171 | c.336C>T p.R112= | Silent (SNP) | VAF 34/412 reads (8%) | catalogued as COSV99854707; called by muse, mutect2
- KDM5A | c.2202C>T p.V734= | Silent (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- KIAA0100 | c.6051G>T p.L2017= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99971967; called by muse, mutect2, varscan2
- MCTP2 | c.1701C>T p.I567= | Silent (SNP) | VAF 42/275 reads (15%) | catalogued as COSV59151683; called by muse, mutect2, varscan2
- NTRK3 | c.2241C>T p.F747= (on ENST00000360948 / NM_001012338.2; = p.F733= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV100712365; called by muse, mutect2, varscan2
- PCDH10 | c.2206C>T p.L736= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1437C>T p.P479= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as rs749533197, COSV53964611; called by muse, mutect2, varscan2
- PLXNB3 | c.207C>T p.G69= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs782745854, COSV62795457; called by muse, mutect2, varscan2
- POLE | c.90G>A p.S30= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs369224511; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PRUNE2 | c.4209T>C p.Y1403= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- PTK2B | c.1443C>T p.L481= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as rs373082114; called by muse, mutect2, varscan2
- RBMXL3 | c.2874C>T p.D958= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as rs868955350, COSV57748323; called by muse, mutect2
- SVEP1 | c.693G>A p.L231= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- TFIP11 | c.306G>A p.E102= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV68020392, COSV68020556; called by muse, mutect2, varscan2
- TRPS1 | c.238C>T p.L80= (on ENST00000220888 / NM_001330599.2; = p.L93= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/264 reads (11%) | catalogued as rs1262271911, COSV55258127; called by muse, mutect2, varscan2
- UBR5 | c.6012G>A p.L2004= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs754624808; called by muse, mutect2, varscan2
- XPNPEP2 | c.1092C>T p.L364= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV100941486; called by muse, mutect2, varscan2
- ZC3H3 | c.954G>A p.S318= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs369410453; called by muse, mutect2, varscan2
- ZFHX4 | c.9105G>A p.V3035= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ZNF737 | c.267G>A p.Q89= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV101417692, COSV71199874; called by muse, mutect2, varscan2
- AC025884.2 | n.710C>T | RNA (SNP) | VAF 26/238 reads (11%) | catalogued as rs1476226395; called by muse, varscan2
- AC092865.4 | chr12:8390916 G>A | 5'Flank (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- CCDC57 | c.2242-5476G>C | Intron (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- MUC19 | n.12691C>A | RNA (SNP) | VAF 60/570 reads (11%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.55G>C | RNA (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-38702G>A | Intron (SNP) | VAF 27/110 reads (25%) | catalogued as COSV58116463; called by muse, mutect2, varscan2
- PDLIM1P2 | chr17:21445499 G>A | 5'Flank (SNP) | VAF 24/150 reads (16%) | called by muse, varscan2
- RBFOX1 | c.1071+493G>T | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as rs529051729; called by muse, mutect2, varscan2
- RPS6KA6 | c.81+1694C>T | Intron (SNP) | VAF 15/128 reads (12%) | called by muse, mutect2, varscan2
- SHANK2 | c.1174+23479C>T | Intron (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- TIE1 | c.-7C>T | 5'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- TTN | c.34354+955G>C | Intron (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- ZNF521 | c.3573+243C>G | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+1344C>G | Intron (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
